Gene-level copy-number profile of tumor specimen TCGA-UY-A9PF-01A from TCGA case TCGA-UY-A9PF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 77.9 years (28,470 days).
Specimen TCGA-UY-A9PF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.867501f3-8e5e-4cf9-9c91-6678b9f55dac.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UY-A9PF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ce2e7c65-428b-40c5-b51a-34fb30cd98e7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 2,099; copy number 2: 3,610; copy number 3: 22,418; copy number 4: 21,449; copy number 5: 4,228; copy number 6: 3,698; copy number 7: 626; copy number 8: 764; copy number 9: 275; copy number 10: 366; copy number 11: 28; copy number 12: 21; copy number 13: 133; copy number 15: 10; copy number 16: 18; copy number 18: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UY-A9PF-01A-11D-A38F-01): tumor purity 0.37, ploidy 3.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,275 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:142,933,195–155,520,353, 221 genes, copy number 7 (broad region; genes not listed).
- chr7:38,239,580–38,318,861, 12 genes, copy number 8: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr8:31,639,222–32,855,666, 1 gene, copy number 7 (within-gene range 3–7): NRG1.
- chr8:32,192,028–37,844,896, 76 genes, copy number 7 (broad region; genes not listed).
- chr8:56,373,064–62,249,879, 83 genes, copy number 9–11 (broad region; genes not listed).
- chr8:69,424,849–113,436,939, 672 genes, copy number 7–18 (within-gene range 5–18) (broad region; genes not listed).
- chr8:113,376,669–119,108,455, 39 genes, copy number 10 (within-gene range 5–10): AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2.
- chr8:120,535,745–127,419,050, 111 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr8:127,079,874–127,092,600, 2 genes, copy number 9 (within-gene range 6–9): PRNCR1, AC020688.1.
- chr8:127,289,817–127,482,139, 1 gene, copy number 9 (within-gene range 6–9): CASC8.
- chr8:127,322,183–127,742,951, 6 genes, copy number 9 (within-gene range 6–9): POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,796,028, 1 gene, copy number 9: MIR1204.
- chr11:30,830,369–31,509,645, 5 genes, copy number 7 (within-gene range 2–7): DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L.
- chr11:65,695,552–93,072,031, 724 genes, copy number 8 (broad region; genes not listed).
- chr14:22,011,910–22,506,702, 68 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr21:10,328,411–29,175,889, 253 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 667. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
